Somatic mutation profile of tumor specimen TCGA-18-5595-01A (aliquot TCGA-18-5595-01A-01D-1632-08) from TCGA case TCGA-18-5595, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.0 years (18,611 days).
Specimen TCGA-18-5595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3f8dffa-4a04-48f2-bfa4-9f6c4e290e80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-5595-11A (Solid Tissue Normal), aliquot TCGA-18-5595-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3d28647-ab3a-4462-acc6-d61d75903381

The open-access MAF lists 266 somatic variants for this specimen: 185 protein-altering or splice-affecting, 67 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 67, Nonsense Mutation 22, RNA 6, Splice Site 4, 3'UTR 3, Intron 3, Frame Shift Del 1, Splice Region 1, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>A p.R505S (on ENST00000281708 / NM_001349798.2; = p.R425S on NM_018315.5) | Missense Mutation (SNP) | VAF 61/147 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 47/114 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50281488, COSV50317507; called by muse, mutect2, varscan2
- NAA15 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 86/202 reads (43%) | catalogued as rs1560966086, COSV56720399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 95/208 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 17/152 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF2 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55184839; called by muse, mutect2, varscan2
- ABCF2 | c.125A>T p.K42M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV55187463; called by muse, mutect2, varscan2
- ACACB | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757955756, COSV58127896, COSV58128229; called by muse, mutect2, varscan2
- ACOT11 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV59352453; called by muse, mutect2
- AGBL5 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59938744; called by muse, mutect2, varscan2
- AIF1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as COSV61962820; called by muse, mutect2, varscan2
- AKAP8 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.027); catalogued as COSV54105354; called by muse, mutect2, varscan2
- AMELX | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 174/205 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs431825176, COSV61637275; ClinVar: not provided; called by muse, mutect2, varscan2
- ANKRD26 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV65799199; called by muse, mutect2, varscan2
- ANKRD34A | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60160244; called by muse, mutect2, varscan2
- ARFGAP2 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 165/383 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53572000; called by muse, mutect2, varscan2
- B4GALNT3 | c.1716G>C p.Q572H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV56758999; called by muse, mutect2, varscan2
- BAHCC1 | c.5653G>A p.E1885K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.149); catalogued as COSV57034640; called by muse, mutect2
- BAIAP3 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 82/509 reads (16%) | catalogued as COSV50105941; called by muse, mutect2, varscan2
- C1QBP | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV56710046; called by muse, mutect2, varscan2
- C22orf31 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53310207, COSV53311388; called by muse, mutect2, varscan2
- CARMIL3 | c.1040T>A p.L347H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57728826; called by muse, mutect2, varscan2
- CCDC125 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67289091; called by muse, mutect2, varscan2
- CCDC93 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV60124821; called by muse, mutect2, varscan2
- CD2BP2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 200/513 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59770076; called by muse, mutect2, varscan2
- CDH23 | c.9741G>C p.L3247= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56494587; called by muse, mutect2
- CDK15 | c.755C>T p.P252L (on ENST00000652192 / NM_001366386.2; = p.P201L on NM_139158.2) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV53639464; called by muse, mutect2, varscan2
- CEP20 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55385330; called by muse, mutect2, varscan2
- CFAP44 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1396572236, COSV55616577; called by muse, mutect2, varscan2
- CMIP | c.1399G>A p.D467N (on ENST00000537098 / NM_198390.2; = p.D373N on NM_030629.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV67700598; called by muse, mutect2, varscan2
- COL11A2 | c.4747G>A p.D1583N (on ENST00000341947 / NM_080680.3; = p.D1476N on NM_080679.2) | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs753728183, COSV59503643; called by muse, mutect2, varscan2
- COX6C | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 149/246 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as COSV52554017, COSV52555074; called by muse, mutect2, varscan2
- CPNE4 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV70201394; called by muse, varscan2
- CR2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs756848982, COSV65510165; called by muse, mutect2, varscan2
- CRNKL1 | c.2284G>C p.E762Q | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58549271; called by muse, mutect2, varscan2
- CSMD2 | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV53888907, COSV53972858; called by muse, mutect2, varscan2
- CT55 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs782056530, COSV52279146; called by muse, mutect2, varscan2
- CUL3 | c.764C>G p.S255* | Nonsense Mutation (SNP) | VAF 100/274 reads (36%) | catalogued as COSV100025133, COSV52371622; called by muse, mutect2, varscan2
- CYC1 | c.795G>C p.Q265H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59644638, COSV59645241; called by muse, varscan2
- CYP4V2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as rs138739819, COSV66507249; ClinVar: uncertain significance; called by muse, mutect2
- CYP7A1 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56962578; called by muse, mutect2
- CYP7A1 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56966263; called by muse, mutect2
- DNAH5 | c.8172C>G p.F2724L | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV54201380, COSV54257640; called by muse, mutect2, varscan2
- DTX4 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs770051308, COSV57096313; called by muse, mutect2, varscan2
- DUXA | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV73729919; called by muse, mutect2, varscan2
- DUXA | c.29T>G p.M10R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV73729920; called by muse, mutect2, varscan2
- DZIP3 | c.2950C>G p.Q984E | Missense Mutation (SNP) | VAF 187/467 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV64311032; called by muse, mutect2, varscan2
- EHBP1 | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV50444067; called by muse, varscan2
- EHBP1 | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV50444140; called by muse, varscan2
- EXTL1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs147835535, COSV65338529; called by muse, mutect2, varscan2
- FAT4 | c.14487G>T p.R4829S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV100629268, COSV100630942, COSV58713022; called by muse, mutect2, varscan2
- FBXO43 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV71055742; called by muse, mutect2
- FCHO1 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV53186051; called by muse, mutect2, varscan2
- FER | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as COSV55308807; called by muse, mutect2, varscan2
- FKBPL | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751670333, COSV64322955; called by muse, mutect2, varscan2
- FMO3 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV63007262; called by muse, mutect2, varscan2
- FMO3 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV63008657, COSV63008791; called by muse, mutect2, varscan2
- FRMPD2 | c.1414G>T p.V472F | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59724589; called by muse, mutect2
- GARRE1 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.059); catalogued as COSV55105306; called by muse, mutect2, varscan2
- GLI1 | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57368401; called by muse, mutect2, varscan2
- GPER1 | c.1053C>A p.F351L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV99867499; called by mutect2, varscan2
- GRAMD1A | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV58769401; called by muse, mutect2
- GRAMD1A | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV58767509; called by muse, mutect2
- GRIN2B | c.3781C>T p.Q1261* | Nonsense Mutation (SNP) | VAF 61/127 reads (48%) | catalogued as rs1555101944, COSV74208344; called by muse, mutect2, varscan2
- H3C7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV55101191; called by muse, mutect2, varscan2
- HEATR3 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV53532035; called by muse, mutect2, varscan2
- HEXA | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV51509343; called by muse, mutect2, varscan2
- HR | c.1592A>C p.D531A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV57195037; called by muse, mutect2, varscan2
- HSD17B11 | c.735G>C p.R245S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV64155471; called by muse, mutect2, varscan2
- HSD3B1 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs1212501858, COSV52492654; called by muse, mutect2, varscan2
- HSF4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.07); catalogued as rs778828995, COSV50460396; called by muse, mutect2, varscan2
- HTR6 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57034015; called by muse, mutect2, varscan2
- HYDIN | c.9242C>A p.A3081E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV59266730, COSV59273323; called by mutect2, varscan2
- IFT122 | c.2836C>T p.Q946* (on ENST00000348417 / NM_052989.3; = p.Q887* on NM_018262.4) | Nonsense Mutation (SNP) | VAF 129/263 reads (49%) | catalogued as COSV56209382; called by muse, mutect2, varscan2
- IGHD | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1186087497, COSV66655541; called by muse, mutect2, varscan2
- ITIH3 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1230539915, COSV56259195; called by muse, mutect2, varscan2
- KATNIP | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 146/311 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751852302, COSV55189145; called by mutect2, varscan2
- KCNMA1 | c.541-1G>A p.X181_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54228596; called by muse, mutect2
- KEAP1 | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV50645628, COSV50657104; called by muse, mutect2, varscan2
- KIF21B | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as rs768350530, COSV59768400; called by muse, mutect2, varscan2
- KRT84 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 48/92 reads (52%) | catalogued as COSV57774107; called by muse, mutect2, varscan2
- LAMA2 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 79/169 reads (47%) | catalogued as COSV70356805; called by muse, mutect2, varscan2
- LIG4 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63598293; called by muse, mutect2, varscan2
- LILRA1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as rs530732441, COSV52182590; called by muse, varscan2
- LOXL2 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279083736, COSV66693986; called by muse, mutect2, varscan2
- LRRC55 | c.865T>A p.W289R | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV73007082; called by muse, mutect2
- LRRK2 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV54174538; called by muse, mutect2, varscan2
- MAGEA12 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63295623; called by muse, mutect2
- MAGT1 | c.620G>C p.R207T (on ENST00000618282 / NM_001367916.1; = p.R239T on NM_032121.5) | Missense Mutation (SNP) | VAF 84/101 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV63783331, COSV63783376; called by muse, mutect2, varscan2
- MANEA | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62589329, COSV62590817; called by muse, mutect2, varscan2
- MAP7D2 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 129/151 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV65530978; called by muse, mutect2, varscan2
- MAPK4 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68544184; called by muse, mutect2, varscan2
- MBIP | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV59255331, COSV59255509; called by muse, mutect2, varscan2
- MCM7 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs549764255, COSV57999574; called by muse, mutect2, varscan2
- MED12L | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1216871961, COSV56400734; called by muse, mutect2, varscan2
- MGA | c.7435G>A p.D2479N (on ENST00000219905 / NM_001164273.1; = p.D2270N on NM_001080541.2) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209599969, COSV54964672; called by muse, mutect2, varscan2
- MIOS | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1344097191, COSV60771080; called by muse, mutect2, varscan2
- MMP14 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61289839; called by muse, mutect2, varscan2
- MPPED2 | c.537-2A>T p.X179_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV63901833; called by muse, mutect2, varscan2
- MRNIP | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs1165114847, COSV52975823; called by muse, mutect2, varscan2
- MTMR3 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.197); catalogued as COSV60306133; called by muse, mutect2, varscan2
- MTX3 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); catalogued as COSV72512562; called by muse, mutect2, varscan2
- MUC16 | c.26902C>G p.P8968A | Missense Mutation (SNP) | VAF 122/272 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.094); catalogued as COSV67500593; called by muse, mutect2, varscan2
- MYH6 | c.4744G>A p.D1582N | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs1050811589, COSV62455027; called by muse, mutect2, varscan2
- MYLK | c.4118C>T p.S1373L | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV60624733; called by muse, mutect2, varscan2
- NBEA | c.6650C>G p.S2217* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV59784798, COSV59830078; called by muse, mutect2, varscan2
- NCOA1 | c.4044G>T p.M1348I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV56054588; called by muse, mutect2, varscan2
- NCOA6 | c.2746A>T p.K916* | Nonsense Mutation (SNP) | VAF 30/240 reads (13%) | catalogued as COSV62868760; called by muse, mutect2, varscan2
- NELFB | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as rs1297574121, COSV58026726; called by muse, mutect2, varscan2
- NT5C2 | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58419885; called by muse, varscan2
- NUDT14 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV59307596; called by muse, mutect2, varscan2
- OBSCN | c.4052C>A p.A1351E | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.694); catalogued as COSV52841332; called by muse, mutect2, varscan2
- OR2AK2 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63562991; called by muse, mutect2, varscan2
- OSGIN2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV52412006; called by muse, mutect2, varscan2
- P4HTM | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV59089542; called by muse, mutect2, varscan2
- PARP9 | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV64452250; called by muse, mutect2, varscan2
- PCDH10 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV52101045, COSV52105935; called by muse, mutect2, varscan2
- PCDHGB2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54051058; called by muse, mutect2, varscan2
- PCF11 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53538690; called by muse, mutect2, varscan2
- PCF11 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53528191; called by muse, mutect2, varscan2
- PEAK1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 88/199 reads (44%) | catalogued as COSV56931413, COSV56944905; called by muse, mutect2, varscan2
- PFKM | c.85+1G>T p.X29_splice | Splice Site (SNP) | VAF 8/59 reads (14%) | catalogued as COSV56660936; called by muse, mutect2, varscan2
- PGAP4 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV66387716; called by muse, mutect2, varscan2
- PLEKHA5 | c.3060G>C p.M1020I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779982258, COSV54714358; called by muse, mutect2, varscan2
- PPIL1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs770897099, COSV65473140; called by muse, mutect2, varscan2
- PTPRU | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60537968; called by muse, mutect2, varscan2
- RABEP2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62871298; called by muse, mutect2, varscan2
- RBP2 | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 134/327 reads (41%) | catalogued as rs1250779773, COSV51675310; called by muse, mutect2, varscan2
- RGS22 | c.1868C>G p.S623C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62668845; called by muse, mutect2, varscan2
- RILP | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs757208734, COSV53961829; called by muse, mutect2, varscan2
- ROBO1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1420699702, COSV71399305; called by muse, mutect2, varscan2
- ROBO2 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV59945786; called by muse, mutect2
- RPS6KC1 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV65303323; called by muse, mutect2, varscan2
- RYR3 | c.12349G>A p.E4117K (on ENST00000389232; = p.E4118K on NM_001036.6) | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV66803492; called by muse, mutect2, varscan2
- SAMD15 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53628265; called by muse, mutect2
- SERPINB1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV66313937; called by muse, mutect2, varscan2
- SKA1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as rs748630272, COSV53279972; called by muse, mutect2, varscan2
- SLC17A1 | c.35-1G>A p.X12_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55082896; called by muse, mutect2
- SLC5A11 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764495479, COSV61740375; called by muse, mutect2, varscan2
- SMARCAD1 | c.2306C>G p.T769R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV62776511; called by muse, mutect2, varscan2
- SNAPC4 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV53738701; called by muse, mutect2, varscan2
- SOGA3 | c.2163G>C p.Q721H | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs893690783, COSV64109194; called by muse, mutect2, varscan2
- SPTBN4 | c.5729C>T p.A1910V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58960728; called by muse, mutect2, varscan2
- SREBF2 | c.2254A>T p.S752C | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV63332994; called by muse, mutect2
- STK17B | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV55830372; called by muse, mutect2, varscan2
- STK36 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as COSV55331470; called by muse, mutect2, varscan2
- STPG3 | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764319164, COSV58026211, COSV58026717; called by muse, mutect2, varscan2
- SYN3 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as COSV60508829; called by muse, mutect2, varscan2
- SYNE2 | c.6464G>A p.R2155K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV59973653; called by muse, mutect2, varscan2
- SYNE2 | c.6465A>T p.R2155S | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV59947645; called by muse, mutect2, varscan2
- TARBP1 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 98/245 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV50212981; called by muse, mutect2, varscan2
- TASOR | c.1711C>T p.R571* (on ENST00000355628 / NM_001365636.2; = p.R175* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 44/107 reads (41%) | catalogued as COSV62930105; called by muse, mutect2, varscan2
- TLN2 | c.4959C>G p.I1653M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs1421447074, COSV60897091; called by muse, mutect2, varscan2
- TMEM132B | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 157/364 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs199976507, COSV54744376; called by muse, mutect2, varscan2
- TMEM132B | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV54773845; called by muse, mutect2, varscan2
- TMEM174 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.127); catalogued as COSV57114482; called by muse, mutect2, varscan2
- TNXB | c.11189A>T p.Y3730F (on ENST00000647633; = p.Y3483F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs763131927, COSV64490640; called by muse, mutect2, varscan2
- TRIOBP | c.6010G>A p.E2004K (on ENST00000644935 / NM_001039141.3; = p.E291K on NM_007032.5) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV58526067; called by muse, mutect2
- TRPC1 | c.1028G>T p.R343L (on ENST00000476941 / NM_001251845.2; = p.R309L on NM_003304.4) | Missense Mutation (SNP) | VAF 136/198 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56431118; called by muse, mutect2, varscan2
- TSEN2 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV53191448; called by muse, mutect2, varscan2
- TSSK6 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1568355747, COSV53065508; called by muse, mutect2, varscan2
- TSSK6 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV53065512; called by muse, mutect2, varscan2
- TUT4 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.41); catalogued as COSV57120614; called by muse, mutect2, varscan2
- UBA3 | c.1302A>T p.K434N | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV62741745; called by muse, mutect2, varscan2
- UBR4 | c.11239G>A p.D3747N | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64402069; called by muse, mutect2, varscan2
- UNC5D | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs776286236, COSV54768799; called by muse, mutect2, varscan2
- USF3 | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV57070107; called by muse, mutect2, varscan2
- USP2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV52732722; called by muse, mutect2, varscan2
- USP25 | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV53491387; called by muse, mutect2
- USP54 | c.3982C>A p.Q1328K | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60444419; called by muse, mutect2, varscan2
- WARS2 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52483290; called by muse, mutect2, varscan2
- WDR93 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV51536185; called by muse, mutect2
- YEATS2 | c.4192C>T p.H1398Y | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV59373491; called by muse, mutect2, varscan2
- ZMYM5 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 114/237 reads (48%) | catalogued as rs764510379, COSV61990490; called by muse, mutect2, varscan2
- ZNF106 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV55522750; called by muse, mutect2, varscan2
- ZNF236 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 69/182 reads (38%) | catalogued as COSV53499904; called by muse, mutect2, varscan2
- ZNF33A | c.1946C>T p.S649L (on ENST00000458705 / NM_006974.3; = p.S650L on NM_006954.2) | Missense Mutation (SNP) | VAF 90/127 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV56728354; called by muse, mutect2, varscan2
- ZNF396 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 65/163 reads (40%) | catalogued as COSV60475526; called by muse, mutect2, varscan2
- ZNF534 | c.368G>T p.G123V (on ENST00000332323 / NM_001143939.3; = p.G110V on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56520802, COSV56521770; called by muse, mutect2, varscan2
- ZP1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53927314; called by muse, mutect2, varscan2
- ZPLD1 | c.347T>A p.V116D (on ENST00000466937 / NM_001329788.1; = p.V132D on NM_175056.2) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV60356627; called by muse, mutect2, varscan2
- CAPG | c.551_555del p.I184Rfs*16 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- EPB41L1 | c.32dup p.K12Efs*35 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | called by mutect2, pindel, varscan2
- ZNF26 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF658 | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 50/426 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- A2M | c.3930G>A p.G1310= | Silent (SNP) | VAF 28/284 reads (10%) | catalogued as COSV59393697; called by muse, mutect2
- AADAT | c.567C>T p.N189= | Silent (SNP) | VAF 108/253 reads (43%) | catalogued as rs760865515, COSV61788287; called by muse, mutect2, varscan2
- ADAM12 | c.378G>T p.R126= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV64115983; called by muse, mutect2, varscan2
- ALPL | c.138C>T p.L46= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV66381075; called by muse, mutect2, varscan2
- ANKRD11 | c.1956G>A p.L652= | Silent (SNP) | VAF 136/341 reads (40%) | catalogued as COSV56374354; called by muse, mutect2, varscan2
- ANO3 | c.252G>A p.E84= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV56811772; called by muse, mutect2, varscan2
- ANXA11 | c.1320C>A p.L440= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV55419111; called by muse, mutect2, varscan2
- C1orf112 | c.1140C>T p.L380= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV53680607, COSV99610142; called by muse, mutect2, varscan2
- CD6 | c.1194G>A p.E398= | Silent (SNP) | VAF 80/350 reads (23%) | catalogued as COSV57843586; called by muse, mutect2, varscan2
- CHAD | c.543C>T p.N181= | Silent (SNP) | VAF 77/207 reads (37%) | catalogued as rs542700767, COSV51974381; called by muse, mutect2, varscan2
- CHODL | c.354C>A p.L118= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV54735685; called by muse, mutect2, varscan2
- CPNE2 | c.504G>A p.K168= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51965607; called by muse, mutect2, varscan2
- CSE1L | c.2709C>T p.F903= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV53705609; called by muse, mutect2, varscan2
- CTNNAL1 | c.1329G>A p.Q443= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV57705999; called by muse, mutect2, varscan2
- CYC1 | c.942G>A p.L314= | Silent (SNP) | VAF 43/77 reads (56%) | catalogued as COSV59645251; called by muse, mutect2, varscan2
- DNAH2 | c.7920C>T p.I2640= | Silent (SNP) | VAF 77/184 reads (42%) | catalogued as COSV66728686; called by muse, mutect2, varscan2
- EFHB | c.1710C>T p.F570= | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as COSV55554752; called by muse, mutect2, varscan2
- ESRRA | c.1161C>A p.L387= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV50008518; called by muse, mutect2, varscan2
- F10 | c.696C>G p.L232= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as COSV65023319; called by muse, mutect2, varscan2
- FAM83B | c.1392G>T p.R464= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV60927833, COSV60927877; called by muse, mutect2, varscan2
- FBXO43 | c.1809A>T p.G603= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as COSV71055675, COSV71055732; called by muse, mutect2
- FSD1 | c.1032A>T p.T344= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV55699416; called by muse, mutect2, varscan2
- GCN1 | c.5094G>A p.P1698= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs374653044; called by muse, mutect2, varscan2
- GPR161 | c.1128G>A p.A376= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs749516474, COSV54795449; called by muse, mutect2, varscan2
- HFM1 | c.3003G>A p.T1001= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1333512848, COSV54021433; called by muse, mutect2, varscan2
- HPSE2 | c.858G>A p.L286= | Silent (SNP) | VAF 87/188 reads (46%) | catalogued as COSV65204146; called by muse, mutect2, varscan2
- IRX5 | c.1188G>A p.T396= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs767854433, COSV58059026; called by muse, mutect2, varscan2
- KLHL24 | c.1113A>G p.R371= | Silent (SNP) | VAF 54/645 reads (8%) | catalogued as COSV54429264; called by muse, mutect2
- KPNA4 | c.1524C>T p.F508= | Silent (SNP) | VAF 110/572 reads (19%) | catalogued as COSV62077171; called by muse, varscan2
- LMOD1 | c.51C>T p.I17= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs777412635, COSV66174113; called by muse, mutect2, varscan2
- LPAR2 | c.264C>T p.L88= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs377707999; called by muse, mutect2, varscan2
- LRIG2 | c.192G>T p.P64= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as COSV100742869, COSV63164608; called by muse, mutect2, varscan2
- LRP1 | c.9711G>A p.L3237= | Silent (SNP) | VAF 264/635 reads (42%) | catalogued as COSV54529012; called by muse, mutect2, varscan2
- MED13L | c.385C>T p.L129= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV56132331; called by muse, varscan2
- MIB1 | c.1257G>A p.L419= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV55095762; called by muse, mutect2, varscan2
- MN1 | c.186C>T p.G62= | Silent (SNP) | VAF 68/130 reads (52%) | catalogued as COSV56563085; called by muse, mutect2, varscan2
- NCOA6 | c.2745G>A p.K915= | Silent (SNP) | VAF 31/239 reads (13%) | catalogued as rs1347513922, COSV62868767; called by muse, mutect2, varscan2
- OR2B3 | c.459C>T p.F153= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs139179669, COSV65850831; called by muse, mutect2, varscan2
- PCDHB8 | c.207C>T p.S69= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as COSV99177325; called by muse, mutect2, varscan2
- PCDHGA6 | c.1827C>T p.L609= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV54051068; called by muse, mutect2
- PEAK1 | c.2433G>A p.K811= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as rs749268448, COSV56944883; called by muse, mutect2, varscan2
- PEAR1 | c.741C>T p.S247= | Silent (SNP) | VAF 41/329 reads (12%) | catalogued as rs1368844844, COSV52776523; called by muse, mutect2, varscan2
- PKP3 | c.1107C>T p.L369= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV58990509; called by muse, mutect2, varscan2
- PLEC | c.6762G>T p.L2254= (on ENST00000322810 / NM_201380.4; = p.L2144= on NM_000445.5) | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV59705269; called by muse, mutect2, varscan2
- PNPLA6 | c.1170C>T p.T390= (on ENST00000414982 / NM_001166111.2; = p.T342= on NM_006702.5) | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs763107646, COSV55386600; called by muse, mutect2, varscan2
- PRG3 | c.58C>T p.L20= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV54664913; called by muse, mutect2, varscan2
- PROX1 | c.1809G>A p.L603= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV54784749; called by muse, mutect2, varscan2
- PTPRU | c.3765G>A p.Q1255= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV60534211, COSV60537985; called by muse, mutect2, varscan2
- QSOX2 | c.1506C>T p.L502= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs369245620; called by muse, mutect2, varscan2
- SBF1 | c.3651C>T p.V1217= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs749839491, COSV62366405; called by muse, mutect2, varscan2
- SERPINA5 | c.274C>T p.L92= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs747848131, COSV61575252; called by muse, mutect2
- SH2D3A | c.1730G>A p.*577= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs866866534, COSV55589082; called by muse, mutect2, varscan2
- SLC22A4 | c.174G>C p.L58= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV52357038; called by muse, mutect2, varscan2
- SLC27A3 | c.2103G>C p.V701= (on ENST00000271857; = p.V573= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/300 reads (45%) | catalogued as COSV55166124; called by muse, mutect2, varscan2
- SPHK1 | c.418C>T p.L140= (on ENST00000392496 / NM_001355139.2; = p.L154= on NM_021972.4) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV60068416; called by muse, mutect2
- TANC1 | c.1656G>A p.L552= | Silent (SNP) | VAF 82/184 reads (45%) | catalogued as COSV55099145; called by muse, mutect2, varscan2
- TMEM43 | c.87G>A p.L29= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs1458468961, COSV55500719; called by muse, mutect2, varscan2
- TONSL | c.3525G>A p.L1175= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as rs782105382, COSV68049645; called by muse, mutect2, varscan2
- TRPV3 | c.1584C>T p.I528= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV56796576; called by muse, mutect2, varscan2
- TSPAN33 | c.792C>T p.I264= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV56828158; called by muse, mutect2, varscan2
- TUBA1C | c.1191G>A p.L397= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as COSV56511964; called by muse, mutect2, varscan2
- TUBD1 | c.909C>T p.L303= | Silent (SNP) | VAF 80/349 reads (23%) | catalogued as rs534610332, COSV57874955; called by muse, mutect2, varscan2
- WDR18 | c.1218G>A p.E406= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52122815, COSV52123893; called by muse, mutect2, varscan2
- XXYLT1 | c.363G>A p.A121= | Silent (SNP) | VAF 64/99 reads (65%) | catalogued as COSV58756828; called by muse, mutect2, varscan2
- ZBTB20 | c.483C>T p.G161= (on ENST00000474710 / NM_001164342.2; = p.G88= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs772400910, COSV61849791; called by muse, mutect2, varscan2
- ZPLD1 | c.348C>G p.V116= (on ENST00000466937 / NM_001329788.1; = p.V132= on NM_175056.2) | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV60356636; called by muse, mutect2, varscan2
- ZYX | c.330G>A p.E110= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV59557942; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288230C>T | Intron (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502606 G>A | 5'Flank (SNP) | VAF 30/86 reads (35%) | catalogued as rs920080166; called by muse, mutect2, varscan2
- ATAD3B | c.*700C>T | 3'UTR (SNP) | VAF 14/118 reads (12%) | catalogued as rs752824611, COSV58023624; called by muse, mutect2, varscan2
- ATE1 | c.942+976A>G | Intron (SNP) | VAF 47/119 reads (39%) | catalogued as rs749329104, COSV56444435; called by muse, mutect2, varscan2
- CSF3R | c.*173G>A | 3'UTR (SNP) | VAF 24/58 reads (41%) | catalogued as rs777880216, COSV58967622; called by muse, mutect2, varscan2
- DNM1P46 | n.148G>A | RNA (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- DSCR4 | n.125C>T | RNA (SNP) | VAF 20/47 reads (43%) | catalogued as rs148504310; called by muse, mutect2, varscan2
- HABP2 | c.*1G>T | 3'UTR (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100668125; called by muse, varscan2
- MIR205 | n.35C>T | RNA (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- OR3A4P | n.463C>T | RNA (SNP) | VAF 55/130 reads (42%) | catalogued as rs1225511469; called by muse, mutect2, varscan2
- OR3A4P | n.789C>T | RNA (SNP) | VAF 96/235 reads (41%) | called by muse, mutect2, varscan2
- PDE4D | c.455+124796G>A | Intron (SNP) | VAF 67/147 reads (46%) | catalogued as COSV100509307, COSV100509515; called by muse, mutect2, varscan2
- PSMD7 | c.-1G>C | 5'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99542725, COSV99542871; called by muse, mutect2
- SSX6P | n.92C>A | RNA (SNP) | VAF 208/257 reads (81%) | called by muse, mutect2, varscan2
